Somatic mutation profile of tumor specimen TCGA-VS-A9UD-01A (aliquot TCGA-VS-A9UD-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 73.4 years (26,815 days).
Specimen TCGA-VS-A9UD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 680880f1-d72c-4f7e-9a6b-ef611ccf07c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UD-10A (Blood Derived Normal), aliquot TCGA-VS-A9UD-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07653ac4-aca3-41f2-b3c4-b92c553ec6cc

The open-access MAF lists 210 somatic variants for this specimen: 138 protein-altering or splice-affecting, 67 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 67, Nonsense Mutation 12, Intron 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2851G>A p.G951R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060499936, COSV100759350; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABL2 | c.703G>A p.E235K (on ENST00000502732 / NM_007314.4; = p.E220K on NM_005158.5) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100772627, COSV100773109; called by muse, mutect2, varscan2
- ACKR1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1216886104, COSV63674830; called by muse, mutect2, varscan2
- ADCY5 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV100568388; called by muse, mutect2, varscan2
- ADGRB1 | c.4187G>A p.R1396H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.964); catalogued as rs764161080, COSV100030589; called by muse, mutect2, varscan2
- ALPK3 | c.3490C>T p.R1164W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779709566, COSV99362179; called by muse, mutect2, varscan2
- ANKFN1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs150654625; called by muse, mutect2, varscan2
- ANKRD50 | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101539071; called by muse, mutect2, varscan2
- AP2B1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99251843; called by muse, mutect2, varscan2
- ARHGAP12 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100260999, COSV60961050; called by muse, mutect2
- ATG2B | c.4126G>A p.D1376N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99952097; called by muse, mutect2
- BACE1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs756600885, COSV100475410; called by muse, mutect2, varscan2
- BFSP1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100925469; called by muse, mutect2, varscan2
- BICC1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488939371, COSV54064217; called by muse, mutect2, varscan2
- BRWD3 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV100956667; called by muse, mutect2, varscan2
- CAPZB | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs1467668376, COSV99940450; called by muse, mutect2, varscan2
- CASR | c.2551G>A p.E851K (on ENST00000490131; = p.E928K on NM_000388.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1346664029, COSV99949611; called by muse, mutect2, varscan2
- CCNI2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770435493, COSV101107909; called by muse, mutect2, varscan2
- CEP350 | c.4747G>C p.D1583H | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100855444, COSV62608687; called by muse, mutect2, varscan2
- CFAP61 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99847079; called by muse, mutect2, varscan2
- CIT | c.2072T>C p.V691A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1566020550, COSV99951397; called by muse, mutect2, varscan2
- CLTCL1 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99596075; called by muse, mutect2, varscan2
- COL2A1 | c.4255G>A p.V1419M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs371226850; called by muse, mutect2, varscan2
- CPED1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV59997025; called by muse, mutect2, varscan2
- CSMD2 | c.4513C>T p.R1505W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs867644442, COSV53976721; called by muse, mutect2, varscan2
- CYFIP2 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.863); catalogued as rs746795054, COSV100558016; called by muse, mutect2, varscan2
- DDX11 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0.041); catalogued as rs201855939, COSV99300494; called by muse, mutect2, varscan2
- DDX3X | c.1595G>A p.G532E (on ENST00000399959; = p.G533E on NM_001356.5) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101302538; called by muse, mutect2, varscan2
- DIAPH2 | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 43/72 reads (60%) | catalogued as COSV100236086; called by muse, mutect2, varscan2
- DNAH17 | c.8822G>A p.R2941Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771752094, COSV101103860; called by mutect2, varscan2
- DNAH8 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.065); catalogued as COSV100547478; called by muse, mutect2, varscan2
- DNAJB5 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100258089; called by muse, mutect2, varscan2
- DSG2 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99853657; called by muse, mutect2, varscan2
- ECHDC2 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100597799, COSV64300701, COSV64301721; called by muse, mutect2, varscan2
- EIF2S2 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV66621482; called by muse, mutect2, varscan2
- EIF4A3 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs757442778, COSV99484254; called by muse, mutect2, varscan2
- ENTPD5 | c.596A>T p.D199V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100592407; called by muse, mutect2, varscan2
- EXOC3L2 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.999); catalogued as rs756258972, COSV99374677; called by muse, mutect2, varscan2
- FAM114A1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs944719429, COSV62672373; called by muse, mutect2, varscan2
- FAM126B | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV99628382; called by muse, mutect2, varscan2
- FAM221A | c.856A>G p.K286E | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1368655920, COSV61387307; called by muse, mutect2, varscan2
- FBXO10 | c.804G>A p.W268* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99447419; called by muse, mutect2, varscan2
- FCRL5 | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100709439; called by muse, mutect2, varscan2
- FOXL1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100206459; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1026G>A p.V342= | Splice Region (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100438478; called by muse, mutect2, varscan2
- GABRA4 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as rs770261411, COSV51924008; called by muse, mutect2, varscan2
- GALNT9 | c.1691C>T p.T564M (on ENST00000328957 / NM_001122636.2; = p.T198M on NM_021808.3) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs370241695; called by muse, mutect2, varscan2
- GDI1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as rs782128887, COSV99340993, COSV99341252; called by muse, mutect2, varscan2
- GLI1 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as COSV99954840; called by muse, mutect2, varscan2
- GPAM | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100788494; called by muse, mutect2, varscan2
- GRIN2A | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs1057050893, COSV100411424; called by muse, varscan2
- GRIN2D | c.1763T>C p.M588T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99617130; called by muse, mutect2, varscan2
- H3-3B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV54666696, COSV54666887; called by muse, mutect2, varscan2
- HELZ2 | c.3997C>T p.R1333C (on ENST00000467148 / NM_001037335.2; = p.R764C on NM_033405.3) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs538816738, COSV101427640; called by muse, mutect2, varscan2
- HMCN1 | c.16587G>C p.L5529F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV99637665; called by muse, mutect2, varscan2
- HMG20B | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 85/150 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99503193; called by muse, mutect2, varscan2
- HNRNPD | c.793_794insT p.Q265Lfs*8 | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | catalogued as COSV100003128; called by mutect2, pindel, varscan2
- HOXC13 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673647; called by muse, mutect2, varscan2
- HUWE1 | c.7981G>A p.E2661K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53335778; called by muse, mutect2, varscan2
- ISLR2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1394661016, COSV62301583; called by muse, mutect2, varscan2
- JARID2 | c.2789G>A p.R930Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV100522661, COSV59191973; called by muse, mutect2, varscan2
- JMJD6 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100373404; called by muse, mutect2, varscan2
- KCNK2 | c.673T>C p.S225P (on ENST00000444842 / NM_001017425.3; = p.S210P on NM_014217.4) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV101222393; called by muse, mutect2
- KDM5A | c.2816A>G p.E939G | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV101239103; called by muse, mutect2, varscan2
- KNL1 | c.6894G>T p.Q2298H (on ENST00000346991 / NM_170589.5; = p.Q2272H on NM_144508.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100707191; called by muse, mutect2, varscan2
- LCE3A | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100175092, COSV59551214; called by muse, mutect2, varscan2
- LMNA | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs397517912, CM1410871, COSV100738929; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- LRRIQ1 | c.4567A>T p.T1523S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV101280768; called by muse, mutect2, varscan2
- LUM | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99899226; called by muse, mutect2, varscan2
- LYPLA2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1301660676, COSV100994873; called by muse, mutect2, varscan2
- MAP9 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1191537504, COSV100250902, COSV60903979; called by muse, mutect2, varscan2
- MEP1A | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 35/82 reads (43%) | catalogued as COSV100042615, COSV100042800; called by muse, mutect2, varscan2
- MRTFB | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57955828; called by muse, mutect2, varscan2
- MTCH2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs530710316, COSV56768706; called by muse, mutect2, varscan2
- MTUS2 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV101462419; called by muse, mutect2, varscan2
- MYH13 | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99355945; called by muse, varscan2
- NADK | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.769); catalogued as rs377478067; called by muse, mutect2, varscan2
- NCOR2 | c.3227C>T p.S1076F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100658040; called by muse, mutect2, varscan2
- NEK1 | c.2221C>T p.H741Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101455929, COSV71455887; called by muse, mutect2, varscan2
- NIN | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99815753; called by muse, mutect2, varscan2
- NR5A2 | c.1315C>T p.R439C (on ENST00000367362 / NM_205860.3; = p.R393C on NM_003822.5) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs762506535, COSV52645342; called by muse, mutect2, varscan2
- NUDT10 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782274426, COSV100726865; called by muse, mutect2, varscan2
- OBSCN | c.19444G>A p.V6482I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs767384385, COSV100806553; called by muse, mutect2, varscan2
- OPA3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV54398697; called by muse, mutect2, varscan2
- OR52E4 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100389429; called by muse, mutect2, varscan2
- OR6N1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100625332; called by muse, mutect2, varscan2
- OSBPL10 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.075); catalogued as rs267599767, COSV101160023; called by muse, mutect2, varscan2
- OTOP3 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs758881773, COSV100173137; called by muse, mutect2, varscan2
- PADI6 | c.1899T>G p.F633L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100640050; called by muse, mutect2
- PBRM1 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56301506; called by muse, mutect2, varscan2
- PDYN | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99453450; called by muse, mutect2, varscan2
- PIK3CD | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as rs369126260; called by muse, mutect2, varscan2
- PIK3IP1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.166); catalogued as rs752850127, COSV99314281; called by muse, mutect2, varscan2
- PLK4 | c.2880G>C p.L960F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV99585061; called by muse, mutect2
- PLXNA1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52527874; called by muse, mutect2, varscan2
- PNISR | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as rs544889814, COSV65079966; called by muse, mutect2, varscan2
- POTEE | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 83/120 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs575814817, COSV100389322; called by muse, mutect2, varscan2
- PRICKLE2 | c.2192C>A p.S731* (on ENST00000295902; = p.S675* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as COSV99898223; called by muse, varscan2
- PTPRS | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1447785084, COSV53620614; called by muse, mutect2, varscan2
- RALGAPA1 | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV51898769; called by muse, mutect2, varscan2
- RASGRF1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs754845042, COSV101174855; called by muse, varscan2
- RBL1 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100727353; called by muse, mutect2, varscan2
- RBM44 | c.1061C>T p.P354L (on ENST00000611254; = p.P988L on NM_001080504.2) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1302337059, COSV100390285; called by muse, mutect2, varscan2
- RFX7 | c.3938G>A p.R1313H (on ENST00000559447 / NM_001368074.1; = p.R1410H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs372302469; called by muse, mutect2, varscan2
- RGS12 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60905114; called by muse, mutect2, varscan2
- SERPINA6 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs747671539, COSV58585130; called by muse, mutect2, varscan2
- SLC24A5 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV99982284; called by muse, mutect2, varscan2
- SLC26A9 | c.1107G>C p.M369I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100536947, COSV61601719; called by muse, mutect2
- SLC39A14 | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV99250081; called by muse, mutect2, varscan2
- SLC44A5 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100902846; called by muse, mutect2
- SMG1 | c.9619C>A p.L3207I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV101247014; called by muse, mutect2, varscan2
- ST3GAL3 | c.653C>T p.T218M (on ENST00000361392 / NM_174964.4; = p.T203M on NM_006279.5) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767429776, COSV53510961; called by muse, mutect2, varscan2
- SUPT20H | c.344T>C p.L115S (on ENST00000350612 / NM_001014286.3; = p.L116S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100634867; called by muse, mutect2, varscan2
- SYT6 | c.1429G>A p.D477N (on ENST00000610222 / NM_001366225.1; = p.D392N on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV101059805; called by muse, mutect2, varscan2
- TBC1D10A | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53164505; called by muse, mutect2, varscan2
- TBC1D32 | c.3262C>G p.L1088V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV51548435, COSV99251646; called by muse, mutect2, varscan2
- TEDDM1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100842978; called by muse, mutect2, varscan2
- TMEM38B | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV65950395; called by muse, mutect2, varscan2
- TOPORS | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV62117356; called by muse, mutect2, varscan2
- TRIM45 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.668); catalogued as COSV99868817; called by muse, mutect2, varscan2
- TRPV2 | c.1476C>G p.I492M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as COSV100641227, COSV100641433; called by muse, mutect2, varscan2
- TSPAN6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.163); catalogued as COSV100885967; called by muse, mutect2, varscan2
- TSPYL1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.196); catalogued as rs377352006; called by muse, mutect2, varscan2
- UBR2 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100867576; called by muse, mutect2, varscan2
- UBR5 | c.6391G>C p.E2131Q | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as COSV99642738; called by muse, mutect2, varscan2
- UMODL1 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100210924; called by muse, mutect2, varscan2
- USH2A | c.2743C>A p.P915T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.596); catalogued as COSV100239639; called by muse, mutect2, varscan2
- USP11 | c.2350T>C p.C784R (on ENST00000218348; = p.C741R on NM_001371072.1) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99511251; called by muse, mutect2
- USP31 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99566111; called by muse, mutect2, varscan2
- WDR45B | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV101124478; called by muse, mutect2, varscan2
- XRCC3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.166); catalogued as rs1347713264, COSV100721361; called by muse, mutect2, varscan2
- DLGAP1 | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN1 | c.15382dup p.Y5128Lfs*7 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- SREK1IP1 | c.135C>A p.S45R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TAP2 | c.504_522del p.L168Ffs*3 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by mutect2, pindel, varscan2
- XAB2 | c.346del p.Y116Tfs*60 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- ARID5A | c.189C>T p.V63= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100673679; called by muse, mutect2, varscan2
- BCL11A | c.1422C>T p.S474= (on ENST00000335712 / NM_001365609.1; = p.S508= on NM_018014.4) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV59636753; called by muse, mutect2, varscan2
- CARNMT1 | c.495T>C p.F165= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1345929278, COSV100961137; called by muse, mutect2, varscan2
- CCDC27 | c.1275C>T p.F425= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as rs745496247, COSV99622391, COSV99623067; called by muse, mutect2, varscan2
- CDC37 | c.165C>T p.R55= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs759946976, COSV55769500; called by muse, mutect2, varscan2
- CDC7 | c.1203T>C p.G401= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99320028; called by muse, mutect2, varscan2
- CDIPT | c.63C>T p.F21= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99570326; called by muse, mutect2, varscan2
- CDIPT | c.18C>T p.I6= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs763783272, COSV99570328; called by muse, mutect2, varscan2
- CDK15 | c.699T>C p.S233= (on ENST00000652192 / NM_001366386.2; = p.S182= on NM_139158.2) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99643855; called by muse, mutect2, varscan2
- CHML | c.1689C>T p.S563= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100087980; called by muse, mutect2, varscan2
- CLUH | c.2421C>T p.H807= (on ENST00000435359; = p.H846= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1447387119, COSV101425934; called by muse, mutect2, varscan2
- COMMD4 | c.171C>T p.D57= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs200472461, COSV51191597; called by muse, mutect2, varscan2
- CTSA | c.426T>C p.Y142= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs941611273, COSV99510209; called by muse, mutect2, varscan2
- CYLD | c.2553C>T p.H851= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs370020837; called by muse, mutect2, varscan2
- CYP3A4 | c.1080G>A p.V360= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100315998; called by muse, mutect2, varscan2
- DNAH2 | c.6036C>T p.I2012= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs200342632, COSV101209660; called by muse, mutect2, varscan2
- DZIP1L | c.279C>T p.I93= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV59521278; called by muse, varscan2
- ECM1 | c.1518C>T p.N506= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs756853467, COSV100682394; called by muse, mutect2, varscan2
- EFCAB13 | c.1326C>T p.L442= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100517034; called by muse, mutect2, varscan2
- ERCC3 | c.2172C>T p.A724= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs778824043, COSV99573766; called by muse, mutect2, varscan2
- ERN1 | c.2097C>G p.P699= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV101458620; called by muse, mutect2, varscan2
- FAM126B | c.1071C>G p.L357= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV53775393, COSV99628381; called by muse, mutect2, varscan2
- FBF1 | c.1050C>T p.D350= (on ENST00000586717; = p.D364= on NM_001319193.1) | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs541926169, COSV59863861; called by muse, mutect2, varscan2
- FNDC1 | c.2553G>A p.S851= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs1441317889, COSV99797375; called by muse, mutect2
- GABRR3 | c.348C>T p.D116= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs368459164, COSV72084168; called by muse, mutect2, varscan2
- H1-5 | c.429G>A p.K143= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs780923320, COSV100138139, COSV58898985; called by muse, mutect2, varscan2
- HNF4A | c.120G>A p.T40= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs765851861, COSV100291833; called by muse, mutect2, varscan2
- IGSF10 | c.3039G>A p.Q1013= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99202346; called by muse, mutect2, varscan2
- LIMD1 | c.1059G>A p.S353= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs199819721, COSV99837251; called by muse, mutect2, varscan2
- LRP1 | c.12468C>T p.C4156= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs139325466; called by muse, mutect2, varscan2
- MAGEA8 | c.561C>G p.L187= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99674873; called by muse, mutect2, varscan2
- MAGEC2 | c.165C>T p.F55= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV55999842, COSV99910036; called by muse, mutect2, varscan2
- MAST3 | c.1959C>T p.A653= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs955793999, COSV99446553; called by muse, mutect2, varscan2
- MRPL2 | c.468C>T p.N156= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99432765; called by muse, mutect2, varscan2
- MUC20 | c.2001G>C p.L667= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100291574; called by muse, mutect2, varscan2
- MUC4 | c.15681C>T p.I5227= (on ENST00000463781 / NM_018406.7; = p.I991= on NM_004532.6) | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs1422174165, COSV100206926; called by muse, mutect2, varscan2
- MYH13 | c.1959C>T p.A653= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs747383501, COSV52846825; called by muse, mutect2, varscan2
- NAPG | c.102C>T p.A34= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs375708480; called by muse, varscan2
- NCKAP5 | c.1260G>A p.V420= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV100494859; called by muse, mutect2, varscan2
- NFKBIB | c.243G>A p.S81= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs145220553; called by muse, mutect2, varscan2
- NOTCH3 | c.849C>T p.N283= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as rs759120774, COSV99659280; called by mutect2, varscan2
- PKD2L1 | c.1293C>T p.L431= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs543262797, COSV100559479; called by muse, mutect2, varscan2
- PPARG | c.783G>C p.A261= (on ENST00000287820 / NM_015869.5; = p.A231= on NM_005037.7) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs770030248, COSV55142021; called by muse, mutect2, varscan2
- PPFIA3 | c.741C>T p.A247= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs765171358, COSV100495404; called by muse, mutect2, varscan2
- PPP6R2 | c.1830C>T p.D610= (on ENST00000216061 / NM_001365836.1; = p.D583= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs762160667, COSV99324998; called by muse, mutect2, varscan2
- PTCHD1 | c.1242C>T p.Y414= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV101038071; called by muse, mutect2
- RAB40C | c.822G>A p.S274= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs545420040, COSV50192944; called by muse, mutect2
- RNF220 | c.1257C>T p.G419= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV59190465; called by muse, mutect2, varscan2
- ROBO4 | c.207G>A p.G69= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100127923; called by muse, mutect2, varscan2
- ROS1 | c.1017C>T p.F339= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV100877867; called by muse, mutect2, varscan2
- RPL3 | c.573C>T p.A191= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs767223357, COSV99335363; called by muse, mutect2
- SLC25A29 | c.834C>T p.G278= (on ENST00000359232 / NM_001039355.3; = p.G212= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1029997904, COSV63650666; called by muse, mutect2, varscan2
- SLC39A12 | c.597T>C p.G199= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV101070222; called by muse, mutect2, varscan2
- SLCO6A1 | c.969C>T p.V323= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs866381547, COSV65805356; called by muse, mutect2, varscan2
- SOCS6 | c.492G>A p.P164= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs1468494061, COSV101205901; called by muse, mutect2, varscan2
- SPG7 | c.825C>G p.A275= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99245559; called by muse, mutect2, varscan2
- TBCD | c.1617C>G p.V539= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs371623110, COSV100833867; called by muse, mutect2, varscan2
- TM9SF4 | c.1179C>T p.G393= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs374323189; called by muse, mutect2, varscan2
- TMEM79 | c.1158C>T p.S386= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs535553352, COSV99828205; called by muse, mutect2, varscan2
- TRRAP | c.3045G>A p.R1015= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100723228; called by muse, mutect2, varscan2
- TSSK1B | c.297C>T p.L99= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs888565087, COSV101180922; called by muse, mutect2, varscan2
- TTC16 | c.1050C>T p.G350= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs758902927, COSV100960089; called by muse, mutect2, varscan2
- UBXN6 | c.567C>T p.P189= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs560614219, COSV56677294; called by muse, mutect2, varscan2
- UHRF1 | c.796C>T p.L266= (on ENST00000612630 / NM_001290050.1; = p.L279= on NM_013282.4) | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV99503800; called by muse, mutect2, varscan2
- WBP2 | c.150C>T p.V50= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs761070011, COSV99637746; called by muse, mutect2, varscan2
- WIZ | c.4422C>T p.F1474= (on ENST00000673675 / NM_001371589.1; = p.F379= on NM_021241.3) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99653970; called by muse, mutect2, varscan2
- ZNF750 | c.1593G>A p.T531= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs928667145, COSV99489710; called by muse, mutect2, varscan2
- BAX | c.474+82C>G | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99509332; called by muse, mutect2, varscan2
- MSH5 | c.538-25G>A | Intron (SNP) | VAF 25/68 reads (37%) | catalogued as rs1040535301, COSV65209074; called by muse, mutect2, varscan2
- POM121 | chr7:72948751 G>A | 3'Flank (SNP) | VAF 19/61 reads (31%) | catalogued as rs529742359, COSV99989475; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2051C>T | Intron (SNP) | VAF 20/55 reads (36%) | catalogued as rs750413362, COSV99199832; called by muse, mutect2, varscan2
- ZNF658B | n.2119T>C | RNA (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
